Surgical pathology report (de-identified scan), TCGA case TCGA-AG-4009, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-4009-01A (Primary Tumor).

This is an adenocarcinoma of the colon (in this case a rectal carcinoma, of moderate differentiation, G2, with widespread infiltration of the muscularis, pT2, and also vascular infiltrates L1, V1; there are also free resection margins in the mucosal region with corresponding mucosa, submucosa and muscularis and also in the deep resection margin (circumferential) regular fatty connective tissue and free lymph nodes (pN0).

Tumor classification:

ICDO-DA-M 8140/3 - G 2, pT2, L1, V1, pN0 (0/16). Locally R0

Source: NCI Genomic Data Commons file 26fcf061-7eff-4afb-aa9d-cc1c3d9ea229 (TCGA-AG-4009.45E9E9C7-C49A-4FDE-9F04-48FE9A457DAD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).